Somatic mutation profile of tumor specimen TCGA-VQ-A94P-01A (aliquot TCGA-VQ-A94P-01A-13D-A410-08) from TCGA case TCGA-VQ-A94P, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Body of stomach; Tumor grade: GX; Age at diagnosis: 57.6 years (21,022 days).
Specimen TCGA-VQ-A94P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b229c0a0-491b-4e2a-aaf4-50705c5fb425.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A94P-10A (Blood Derived Normal), aliquot TCGA-VQ-A94P-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03c6f215-75e8-4dbf-a6c6-8a7938f95e75

The open-access MAF lists 57 somatic variants for this specimen: 47 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 47, Silent 10.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.6794T>G p.L2265R (on ENST00000272895 / NM_173076.3; = p.L1947R on NM_015657.3) | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.333); catalogued as COSV99791071; called by muse, mutect2
- ABCB1 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1387356833, COSV55945226, COSV55959906; called by muse, mutect2, varscan2
- ACTRT1 | c.391A>G p.S131G | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV64419128; called by muse, mutect2
- ADAMTS2 | c.3519A>C p.E1173D | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV99283194; called by muse, mutect2
- ADGRG4 | c.5801T>A p.V1934D | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV99796143; called by muse, mutect2
- APOB | c.9988T>G p.F3330V | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.281); catalogued as COSV99266776; called by muse, mutect2
- APOB | c.9290A>C p.K3097T | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51938840, COSV99264964; called by muse, mutect2
- ARHGAP28 | c.620A>T p.K207M (on ENST00000383472 / NM_001366230.1; = p.K48M on NM_001010000.3) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV51632669, COSV99151159; called by muse, mutect2, varscan2
- ARHGAP28 | c.1721A>C p.K574T (on ENST00000383472 / NM_001366230.1; = p.K415T on NM_001010000.3) | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV99151163; called by muse, mutect2, varscan2
- BRD7 | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV101165020; called by muse, mutect2
- CCN4 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1041568300, COSV51534998; called by muse, mutect2, varscan2
- CCNB3 | c.3073T>A p.L1025M | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as COSV52080141, COSV99329469; called by muse, mutect2
- CTNNA2 | c.1694T>G p.V565G | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.543); catalogued as COSV100561481; called by muse, mutect2
- DEPDC7 | c.1049T>C p.L350S (on ENST00000241051 / NM_001077242.2; = p.L341S on NM_139160.2) | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs1236948535, COSV99572827; called by muse, mutect2
- DIAPH2 | c.851T>G p.I284S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61283343; called by muse, mutect2
- EIF3E | c.688G>T p.D230Y | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as COSV55202981, COSV55204341, COSV99623360; called by muse, mutect2, varscan2
- ERBB4 | c.906T>G p.S302R | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99628798; called by muse, mutect2
- EYA1 | c.1602A>C p.K534N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58167021; called by muse, mutect2, varscan2
- FLRT2 | c.1499A>C p.N500T | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as COSV100420742; called by muse, mutect2
- GAB4 | c.1688G>A p.R563Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV101272045; called by muse, mutect2, varscan2
- GALNT14 | c.1298C>A p.S433Y | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100205204; called by muse, mutect2
- HPSE2 | c.563T>G p.L188R | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100986030; called by muse, mutect2
- KCNJ8 | c.993A>C p.E331D | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as COSV99557661; called by muse, mutect2
- LIPI | c.722A>G p.E241G | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.975); catalogued as COSV100753874; called by muse, mutect2
- LRRN3 | c.1886T>G p.L629R | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100072143; called by muse, mutect2
- LRRTM3 | c.992A>T p.K331I | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100791768; called by muse, mutect2
- MAGEA10 | c.819A>C p.Q273H | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV54883133, COSV99726601; called by muse, mutect2, varscan2
- MAGEA12 | c.744A>C p.Q248H | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as COSV100756767, COSV63294236; called by muse, mutect2, varscan2
- MAGEA3 | c.715T>G p.L239V | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1556826840, COSV100939034, COSV100939070; called by muse, mutect2
- MAGEB3 | c.278A>G p.K93R | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as COSV100854753; called by muse, mutect2
- MAGEE2 | c.615A>T p.K205N | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100973169; called by muse, mutect2
- MAPK4 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs754538065, COSV101245729; called by muse, mutect2, varscan2
- MTCL1 | c.2065G>A p.G689R (on ENST00000306329 / NM_001378206.1; = p.G329R on NM_015210.4) | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as rs766408369, COSV60404283; called by muse, mutect2, varscan2
- MYH8 | c.3684G>T p.K1228N | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV101238536; called by muse, mutect2
- MYO1B | c.294A>C p.Q98H | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV100269608; called by muse, mutect2
- NELL1 | c.1988A>G p.K663R | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100119175, COSV100123127; called by muse, mutect2
- NEXMIF | c.2426T>G p.V809G | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV50069919; called by muse, mutect2, varscan2
- NPAP1 | c.1900A>G p.S634G | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV61508397, COSV61512207, COSV99051844; called by muse, mutect2
- OBSCN | c.10880A>G p.K3627R | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs1358824870, COSV99481667; called by muse, mutect2
- OR6K6 | c.923T>C p.L308P (on ENST00000368144; = p.L284P on NM_001005184.1) | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100933767; called by muse, mutect2
- PCLO | c.11969C>A p.P3990H | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1470345548, COSV100434897; called by muse, mutect2
- RP1 | c.868T>G p.L290V | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV55115442; called by muse, mutect2
- SYNE1 | c.9067C>A p.L3023M (on ENST00000367255 / NM_182961.4; = p.L3030M on NM_033071.3) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55025038, COSV99572775; called by muse, mutect2
- TRDMT1 | c.936G>T p.E312D | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV100004052; called by muse, mutect2, varscan2
- TRIM49 | c.979A>C p.S327R | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV61670608; called by muse, mutect2, varscan2
- TUBA1A | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.145); catalogued as COSV99853782; called by muse, mutect2
- SPATA31A1 | c.881A>C p.N294T | Missense Mutation (SNP) | VAF 25/444 reads (6%) | SIFT tolerated (0.95); PolyPhen benign (0.012); called by muse, mutect2
- CNTN3 | c.726T>G p.G242= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV55161904, COSV99725440; called by muse, mutect2, varscan2
- HTR1E | c.1095T>G p.T365= | Silent (SNP) | VAF 7/107 reads (7%) | catalogued as rs1268659011, COSV100541196; called by muse, mutect2
- IGHV1OR21-1 | c.261C>T p.V87= | Silent (SNP) | VAF 14/434 reads (3%) | called by muse, mutect2
- IQCN | c.3151A>C p.R1051= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100828366; called by muse, mutect2, varscan2
- MYO1F | c.2205C>T p.I735= | Silent (SNP) | VAF 18/308 reads (6%) | catalogued as COSV100596898; called by muse, mutect2
- NELL1 | c.700T>C p.L234= | Silent (SNP) | VAF 4/70 reads (6%) | catalogued as COSV100123124; called by muse, mutect2
- OR8D4 | c.94T>C p.L32= | Silent (SNP) | VAF 7/127 reads (6%) | catalogued as COSV58429637; called by muse, mutect2
- PRB1 | c.750T>C p.P250= | Silent (SNP) | VAF 11/198 reads (6%) | catalogued as rs1233515841, COSV53702693, COSV99555979; called by muse, mutect2
- SLC17A9 | c.276C>T p.V92= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs771274361, COSV100947921; called by muse, mutect2, varscan2
- SLC4A10 | c.1644A>C p.A548= (on ENST00000446997 / NM_001354461.2; = p.A518= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as rs1348637136, COSV99764966; called by muse, mutect2
